Somatic mutation profile of tumor specimen TARGET-10-PARRVK-09A (aliquot TARGET-10-PARRVK-09A-01D) from TARGET case TARGET-10-PARRVK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.6 years (6,433 days).
Specimen TARGET-10-PARRVK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc71c257-832b-463d-bb97-f39309afa5df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARRVK-10A (Blood Derived Normal), aliquot TARGET-10-PARRVK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/091e4780-1017-4507-b678-51cf1af63efd

The open-access MAF lists 27 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, 3'UTR 4, 5'UTR 1, 5'Flank 1, Splice Region 1, RNA 1, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD2 | c.4173del p.K1391Nfs*15 | Frame Shift Del (DEL) | VAF 55/138 reads (40%) | catalogued as rs749969667; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, varscan2
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGA | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs78506343, CM0910627, CM930250, COSV57395912, COSV57399852; called by muse, mutect2, varscan2
- RIMS2 | c.4585C>T p.R1529C (on ENST00000666250 / NM_001348490.2; = p.R1100C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775205197; called by muse, mutect2, varscan2
- SCNN1G | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1158703604, COSV55600263; called by muse, mutect2, varscan2
- TRIML2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs772360955; called by muse, mutect2, varscan2
- ZNF710 | c.832G>T p.V278L | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.393); catalogued as COSV51564292; called by muse, mutect2, varscan2
- FCHSD2 | c.2056+1G>A p.X686_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- MTUS1 | c.2288-4del | Splice Region (DEL) | VAF 63/163 reads (39%) | called by mutect2, pindel, varscan2
- MYRF | c.827_828insCCCCTTAA p.K276Nfs*10 (on ENST00000278836 / NM_001127392.3; = p.K267Nfs*10 on NM_013279.4) | Frame Shift Ins (INS) | VAF 35/96 reads (36%) | called by mutect2, pindel, varscan2
- PADI3 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SSX2IP | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRO | c.640A>G p.K214E | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF84 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL27A1 | c.2250C>T p.P750= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs373974606, COSV61931488; called by muse, mutect2, varscan2
- DNAH3 | c.10017C>T p.S3339= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs762933596; called by muse, mutect2
- GBX1 | c.888C>T p.H296= | Silent (SNP) | VAF 73/176 reads (41%) | catalogued as rs762691879; called by muse, mutect2, varscan2
- LRP2 | c.5373C>T p.Y1791= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs753926959; called by muse, mutect2, varscan2
- SLC6A3 | c.660C>T p.G220= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs118141909, COSV54369247; called by muse, mutect2, varscan2
- BCAT2 | c.1140+158G>A | Intron (SNP) | VAF 36/96 reads (38%) | catalogued as COSV60272860; called by muse, mutect2
- CCT7 | c.-31A>T | 5'UTR (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- LRRC37A6P | n.1890C>G | RNA (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- OR4M1 | c.*27T>G | 3'UTR (SNP) | VAF 40/138 reads (29%) | called by muse, mutect2, varscan2
- PDE2A | c.*890C>T | 3'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- SCARB2 | c.*40C>G | 3'UTR (SNP) | VAF 48/94 reads (51%) | catalogued as rs1430326862; called by muse, mutect2, varscan2
- SGK1 | chr6:134177865 C>T | 5'Flank (SNP) | VAF 12/34 reads (35%) | catalogued as rs749008400; called by muse, mutect2, varscan2
- SMIM12 | c.*26G>A | 3'UTR (SNP) | VAF 16/64 reads (25%) | catalogued as rs745728861; called by muse, mutect2, varscan2
